Gene-level copy-number profile of tumor specimen TCGA-10-0930-01A from TCGA case TCGA-10-0930, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.5 years (25,737 days).
Specimen TCGA-10-0930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7ae59829-3d0f-44df-819b-0b9bf21a2e9e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-10-0930-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b43f2365-e93a-4804-95d9-790f41ceef53

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 2,983; copy number 2: 13,930; copy number 3: 14,818; copy number 4: 18,695; copy number 5: 4,418; copy number 6: 3,096; copy number 7: 750; copy number 8: 632; copy number 9: 326; copy number 10: 72.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-10-0930-01A-02D-0399-01): tumor purity 0.66, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:19,455,418–20,037,972, 4 genes (within-gene range 0–2): AC024230.1, AC110767.1, AC114728.1, AC098862.1.
- chr4:30,720,415–31,146,805, 3 genes (within-gene range 0–2): PCDH7, AC097716.1, MTCYBP43.
- chr4:96,841,995–96,857,900, 1 gene: AC096585.1.
- chr13:77,919,689–78,617,328, 1 gene (within-gene range 0–4): OBI1-AS1.
- chr13:78,275,720–87,892,472, 81 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 398 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–8,611,924, 72 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr5:16,853,994–31,329,146, 168 genes, copy number 9 (broad region; genes not listed).
- chr6:40,271,566–44,830,188, 158 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
